Gene-level copy-number profile of tumor specimen ALCH-B2MA-TTP1-A from ALCHEMIST case ALCH-B2MA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.2 years (28,577 days).
Specimen ALCH-B2MA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ef2afb4f-7ab1-449b-a857-3d71fc15f0dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/87614dcc-57dd-4818-8e35-4c1e7c6b5eb7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 510; copy number 1: 566; copy number 2: 12,610; copy number 3: 21,839; copy number 4: 14,793; copy number 5: 5,446; copy number 6: 757; copy number 7: 809; copy number 8: 543; copy number 9: 126; copy number 10: 687; copy number 11: 40; copy number 12: 17; copy number 13: 1; copy number 14: 18; copy number 15: 4; copy number 17: 6; copy number 18: 14; copy number 21: 6; copy number 22: 31; copy number 25: 28; copy number 31: 23; copy number 41: 10.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,228,620–20,277,503, 1 gene: RHPN2P1.
- chr15:50,241,947–50,265,965, 2 genes: HDC, RN7SL494P.
- chr17:22,221,221–22,221,605, 1 gene: FTLP13.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,347 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,365,720–184,123,978, 97 genes, copy number 7–9 (within-gene range 7–13) (broad region; genes not listed).
- chr1:198,156,994–202,341,980, 92 genes, copy number 7 (broad region; genes not listed).
- chr1:203,167,811–205,943,460, 89 genes, copy number 8–25 (broad region; genes not listed).
- chr2:117,180,892–121,040,710, 52 genes, copy number 7: AC092170.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA.
- chr2:171,999,943–174,776,720, 54 genes, copy number 8 (within-gene range 6–8): METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2, AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3.
- chr2:174,747,592–174,787,935, 1 gene, copy number 8 (within-gene range 6–8): CHRNA1.
- chr2:176,077,472–178,830,802, 84 genes, copy number 8–15 (within-gene range 4–15) (broad region; genes not listed).
- chr3:87,594,838–88,467,594, 14 genes, copy number 7: APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA.
- chr3:152,243,828–198,123,232, 787 genes, copy number 7–8 (broad region; genes not listed).
- chr4:51,843,000–56,328,625, 85 genes, copy number 7–41 (within-gene range 2–41) (broad region; genes not listed).
- chr4:141,220,887–141,357,096, 3 genes, copy number 15: ZNF330, AC107220.1, LINC02432.
- chr5:43,874,367–45,895,970, 16 genes, copy number 7: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:4,775,615–4,794,397, 3 genes, copy number 8: AP5Z1, MIR4656, AC092610.1.
- chr7:99,598,267–99,784,248, 9 genes, copy number 7 (within-gene range 4–7): TMEM225B, ZSCAN25, AC005020.1, CYP3A5, CYP3A7-CYP3A51P, CYP3A51P, CYP3A7, CYP3A4, AC069294.1.
- chr8:64,091–64,320, 1 gene, copy number 12: AC144568.1.
- chr8:39,451,045–39,730,065, 3 genes, copy number 7: ADAM3A, AC123767.1, ADAM18.
- chr9:92,205,356–92,210,158, 1 gene, copy number 8: AL136097.2.
- chr12:66,767–34,249,958, 831 genes, copy number 8–11 (broad region; genes not listed).
- chr13:99,962,964–99,997,909, 3 genes, copy number 7: ZIC5, ZIC2, LINC00554.
- chr16:32,600,299–32,788,944, 15 genes, copy number 7–11: AC137800.1, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr17:48,607,232–48,633,572, 3 genes, copy number 8 (within-gene range 3–8): HOXB7, HOXB8, HOXB9.
- chr18:22,699,481–29,548,241, 100 genes, copy number 7–9 (broad region; genes not listed).
- chr19:42,234,583–42,295,797, 4 genes, copy number 7 (within-gene range 4–7): AC006486.1, AC006486.2, ERF, CIC.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
